Somatic mutation profile of tumor specimen ALCH-B1HA-TTP1-A (aliquot ALCH-B1HA-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1HA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.0 years (23,751 days).
Specimen ALCH-B1HA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75e90505-bec3-4eb8-b820-9580189aa8e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1HA-NB1-A (Blood Derived Normal), aliquot ALCH-B1HA-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6f0941b-ba5b-483d-8171-0ebce981f4a4

The open-access MAF lists 963 somatic variants for this specimen: 685 protein-altering or splice-affecting, 192 silent, 86 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 587, Silent 192, Nonsense Mutation 49, Intron 37, 3'UTR 22, Splice Site 17, RNA 14, Frame Shift Del 13, Splice Region 12, 5'Flank 7, Frame Shift Ins 6, 5'UTR 4.

Variants (750 of 963; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.67+1G>A p.X23_splice | Splice Site (SNP) | VAF 102/559 reads (18%) | hotspot (GDC flag); catalogued as CS1511368, COSV62562857; called by muse, mutect2, varscan2
- CNGA3 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 90/637 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as rs774676415, CM014561, COSV55627277; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLA | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs869312163, CM096038, CM160462; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 133/476 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.9633C>A p.N3211K | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs978984063; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.783-2A>T p.X261_splice | Splice Site (SNP) | VAF 50/288 reads (17%) | hotspot (GDC flag); catalogued as COSV52818160, COSV52984227, COSV53085853; called by muse, mutect2, varscan2
- ABCA6 | c.4834C>T p.P1612S | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV52639979; called by muse, mutect2, varscan2
- ABCB5 | c.1342G>T p.D448Y (on ENST00000404938 / NM_001163941.2; = p.D3Y on NM_178559.6) | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747579982, COSV51704563; called by muse, mutect2, varscan2
- ABCD2 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 30/240 reads (13%) | catalogued as COSV58052686; called by muse, mutect2, varscan2
- ABCF2 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 49/426 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs769829454; called by muse, mutect2, varscan2
- ABCG8 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 76/514 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV55390520; called by muse, mutect2, varscan2
- ABT1 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782312171, COSV51293505; called by muse, mutect2
- AC127029.3 | c.725C>A p.T242K | Missense Mutation (SNP) | VAF 77/534 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.107); catalogued as COSV100033362; called by muse, mutect2, varscan2
- ACACB | c.1426C>A p.L476I | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV100623232; called by muse, mutect2
- ACADM | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 40/413 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201221339; called by muse, mutect2, varscan2
- ACAN | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as rs757439227, COSV61367069; called by muse, mutect2, varscan2
- ACSF2 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as rs374266045; called by muse, mutect2, varscan2
- ADAMTS16 | c.3470G>T p.G1157V | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV56978834; called by muse, mutect2, varscan2
- ADAMTS20 | c.4556C>A p.P1519H | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67130289; called by muse, mutect2, varscan2
- ADD2 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.129); catalogued as rs782815520, COSV52468782; called by muse, mutect2, varscan2
- ADGRL4 | c.1756C>A p.L586I | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as COSV66059465; called by muse, varscan2
- AL121900.1 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 58/317 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.941); catalogued as rs1202999595; called by muse, mutect2, varscan2
- ANKFN1 | c.3504G>T p.L1168F (on ENST00000653862; = p.L1021F on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.82); catalogued as rs1259878752; called by muse, mutect2, varscan2
- ANKRD63 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as rs1333677099; called by muse, mutect2, varscan2
- ANKS1B | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324597789; called by muse, mutect2, varscan2
- ARMC4 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs770059788; called by muse, mutect2, varscan2
- ARPP21 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 38/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs778238399; called by muse, mutect2, varscan2
- ASTN1 | c.1189G>T p.G397C | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV56074842; called by muse, mutect2
- ATN1 | c.2998C>T p.R1000* | Nonsense Mutation (SNP) | VAF 47/286 reads (16%) | catalogued as COSV100755601; called by muse, mutect2, varscan2
- ATP12A | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54513500, COSV54515319; called by muse, mutect2, varscan2
- B3GALT4 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 43/201 reads (21%) | catalogued as COSV65852440; called by muse, mutect2, varscan2
- B3GAT3 | c.81C>T p.L27= | Splice Region (SNP) | VAF 35/222 reads (16%) | catalogued as rs748566255; called by muse, mutect2, varscan2
- BEAN1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.28); catalogued as rs983477217; called by muse, mutect2, varscan2
- BEGAIN | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs200143180; called by muse, mutect2, varscan2
- BMI1 | c.266-8C>T | Splice Region (SNP) | VAF 23/177 reads (13%) | catalogued as rs1240699041; called by muse, mutect2, varscan2
- BOD1L1 | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 27/251 reads (11%) | catalogued as COSV50055817; called by muse, mutect2, varscan2
- BOK | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765671952; called by muse, mutect2, varscan2
- BRAF | c.1906G>T p.G636C (on ENST00000288602 / NM_001374244.1; = p.G596C on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs121913361, COSV56066561, COSV56185580, COSV56316158, COSV99954791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRSK2 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs369672997; called by muse, mutect2, varscan2
- BSN | c.8920G>C p.A2974P | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99609426; called by muse, mutect2
- C6orf118 | c.1375C>G p.Q459E | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.015); catalogued as rs760965461, COSV100024217; called by muse, mutect2, varscan2
- C8orf48 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.121); catalogued as rs190827878, COSV52047964; called by muse, mutect2, varscan2
- CACNA1C | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs749031775, COSV59702701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASP9 | c.1159-3C>A | Splice Region (SNP) | VAF 40/193 reads (21%) | catalogued as rs543529454; called by muse, mutect2, varscan2
- CCDC191 | c.1823C>A p.S608* | Nonsense Mutation (SNP) | VAF 26/207 reads (13%) | catalogued as COSV55670367; called by muse, mutect2, varscan2
- CD109 | c.3567G>T p.K1189N | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs772054494; called by muse, mutect2, varscan2
- CD1A | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56863010, COSV99192721; called by muse, mutect2
- CD93 | c.77C>A p.T26K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs368421659; called by muse, varscan2
- CDCP2 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs759128689, COSV61282899; called by muse, mutect2, varscan2
- CDH18 | c.2161G>T p.A721S | Missense Mutation (SNP) | VAF 57/520 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.134); catalogued as COSV56936228, COSV56953994; called by muse, mutect2, varscan2
- CDH22 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 64/369 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs150995142; called by muse, mutect2, varscan2
- CDKN2A | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100448219, COSV58684018; called by muse, mutect2, varscan2
- CEP192 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as COSV58059562; called by muse, mutect2, varscan2
- CES3 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs941484361, COSV57595563; called by muse, mutect2, varscan2
- CETN1 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 37/355 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs753278933, COSV59121183; called by muse, mutect2, varscan2
- CFAP65 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs1553527951, COSV58565735; called by muse, mutect2, varscan2
- CHL1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV56605429; called by muse, mutect2, varscan2
- COBL | c.3401G>T p.G1134V | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99474463; called by muse, mutect2, varscan2
- COL27A1 | c.3718G>T p.G1240C | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100621317; called by muse, mutect2, varscan2
- COL6A3 | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 48/558 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs556864605; ClinVar: uncertain significance; called by muse, mutect2
- COMMD8 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV67500388; called by muse, mutect2
- CPA6 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs183899632, CM153474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPS1 | c.1755G>T p.M585I | Missense Mutation (SNP) | VAF 146/799 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.119); catalogued as COSV99242816; called by muse, mutect2, varscan2
- CR2 | c.7G>T p.A3S | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.089); catalogued as rs1423906073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRADD | c.500G>T p.W167L | Missense Mutation (SNP) | VAF 57/299 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100257686; called by muse, mutect2, varscan2
- CRB2 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs761359650, COSV100749458; called by muse, mutect2
- CRCT1 | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 32/220 reads (15%) | PolyPhen probably damaging (0.966); catalogued as COSV57500797; called by muse, varscan2
- CRLF1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs370673214; called by muse, mutect2
- CTIF | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs763215980, COSV56490170; called by muse, mutect2, varscan2
- CUBN | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 80/702 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs761726613, COSV100911800, COSV100913410; called by muse, mutect2, varscan2
- CWH43 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750002003, COSV56935780, COSV56939462; called by muse, varscan2
- CXCL3 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as rs372884271; called by muse, mutect2, varscan2
- DAB1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 52/557 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59730408; called by muse, mutect2
- DGKZ | c.1459G>A p.V487M (on ENST00000454345 / NM_001105540.2; = p.V299M on NM_003646.4) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1184358659; called by muse, mutect2
- DLC1 | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as rs764783683; called by muse, mutect2, varscan2
- DLG2 | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 68/397 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV54642409; called by muse, mutect2, varscan2
- DLGAP2 | c.1112G>T p.W371L | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV70097201; called by muse, mutect2, varscan2
- DMBT1 | c.935G>A p.S312N | Missense Mutation (SNP) | VAF 57/376 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.036); catalogued as rs914366621; called by muse, mutect2, varscan2
- DNAJC11 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.08); catalogued as rs375527993; called by muse, mutect2, varscan2
- DOCK7 | c.4755G>T p.E1585D (on ENST00000635253 / NM_001367561.1; = p.E1554D on NM_033407.3) | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV52023397; called by muse, mutect2, varscan2
- DPT | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 61/552 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.201); catalogued as rs745685247; called by muse, mutect2, varscan2
- DSCAM | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.787); catalogued as rs77295141, COSV99064504; called by muse, mutect2, varscan2
- DYSF | c.3406G>A p.G1136S | Missense Mutation (SNP) | VAF 63/410 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs554800123, COSV50327385; called by muse, mutect2, varscan2
- DYSF | c.3407G>T p.G1136V | Missense Mutation (SNP) | VAF 63/412 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CD123556; called by muse, mutect2, varscan2
- EBF2 | c.1589C>A p.S530Y | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.646); catalogued as COSV101282285, COSV68776477; called by muse, mutect2, varscan2
- EFCAB6 | c.2956A>G p.I986V | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV53057930; called by muse, mutect2, varscan2
- ENKUR | c.155C>A p.A52E | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs776798562, COSV58634911; called by muse, mutect2
- ENTPD5 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780875562; called by muse, mutect2, varscan2
- EPG5 | c.3683C>T p.T1228M | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs556565796, COSV56357058; called by muse, mutect2, varscan2
- EPHB3 | c.2391C>T p.G797= | Splice Region (SNP) | VAF 13/73 reads (18%) | catalogued as rs368784730; called by muse, mutect2, varscan2
- EPS8L1 | c.1953-6G>A | Splice Region (SNP) | VAF 30/140 reads (21%) | catalogued as rs931403980, COSV52387374; called by muse, mutect2, varscan2
- EVPL | c.1795G>A p.V599M | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs777161070, COSV56914786; called by muse, mutect2, varscan2
- EXTL1 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746131146, COSV65333313; called by muse, mutect2, varscan2
- FAM114A1 | c.1464-1G>T p.X488_splice | Splice Site (SNP) | VAF 30/170 reads (18%) | catalogued as rs1311938083; called by muse, mutect2, varscan2
- FAM217B | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV100674522; called by muse, mutect2, varscan2
- FAM217B | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as rs1320498194; called by muse, mutect2, varscan2
- FASTKD1 | c.1792G>T p.V598L | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs759405753; called by muse, mutect2
- FBN3 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs774484397, COSV54459899; called by muse, mutect2, varscan2
- FBXW10 | c.2327G>A p.R776Q | Missense Mutation (SNP) | VAF 19/208 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs375352795; called by muse, mutect2
- FCER1A | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.024); catalogued as rs761924240; called by muse, mutect2, varscan2
- FILIP1 | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 95/562 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.102); catalogued as rs777670839, COSV52740985; called by muse, mutect2, varscan2
- FOXF2 | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52527395; called by muse, mutect2, varscan2
- FOXH1 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 108/319 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs753288105; called by muse, mutect2, varscan2
- FOXK1 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1410418718; called by muse, mutect2, varscan2
- FSTL5 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 79/572 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs1018900940, COSV60233284; called by muse, mutect2, varscan2
- FTMT | c.402C>G p.N134K | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58420850; called by muse, mutect2, varscan2
- G3BP1 | c.1266C>G p.D422E | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.987); catalogued as COSV62366864; called by muse, mutect2, varscan2
- GABRA2 | c.1127C>A p.P376Q | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.372); catalogued as COSV100733842, COSV100734631; called by muse, mutect2, varscan2
- GFOD2 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs760542062, COSV99263722; called by muse, mutect2, varscan2
- GINM1 | c.614G>T p.S205I | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66389771; called by muse, mutect2, varscan2
- GMPR2 | c.566G>A p.R189Q (on ENST00000355299 / NM_001351022.2; = p.R207Q on NM_016576.5) | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1394409265, COSV51661606; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1481G>T p.R494L | Missense Mutation (SNP) | VAF 130/570 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV71180667; called by mutect2, varscan2
- GPR45 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1014931172, COSV51523771; called by muse, mutect2, varscan2
- GRIK5 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1055850349, COSV99491116; called by muse, mutect2, varscan2
- GRM4 | c.1663T>A p.Y555N | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV100946467; called by muse, mutect2, varscan2
- HAS3 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs759942773; called by muse, mutect2, varscan2
- HELZ2 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776295297, COSV64410483; called by muse, mutect2, varscan2
- HIVEP2 | c.3959C>T p.S1320L | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs745789310, COSV50005753, COSV50099198; called by muse, mutect2, varscan2
- HNRNPC | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.931); catalogued as COSV60146135; called by muse, mutect2
- IGKV1-12 | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 92/1644 reads (6%) | catalogued as rs1370560652; called by muse, mutect2
- IGKV2D-29 | c.303C>G p.S101R | Missense Mutation (SNP) | VAF 58/577 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV101534350; called by muse, mutect2, varscan2
- IGKV3D-20 | c.56C>A p.T19N | Missense Mutation (SNP) | VAF 45/570 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs376428800; called by muse, mutect2
- IKBKE | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782392890; called by muse, mutect2
- IL16 | c.2420G>T p.R807I (on ENST00000302987 / NM_172217.5; = p.R106I on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV57266590; called by muse, mutect2, varscan2
- IRAK4 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV71210736; called by muse, mutect2, varscan2
- ITGA11 | c.3520C>T p.R1174C | Missense Mutation (SNP) | VAF 54/376 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1378685868, COSV59875216; called by muse, mutect2, varscan2
- ITGAD | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 27/163 reads (17%) | catalogued as COSV66758875; called by muse, mutect2, varscan2
- ITGAE | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 35/177 reads (20%) | catalogued as COSV53993683; called by muse, mutect2, varscan2
- JRKL | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99567635; called by muse, mutect2, varscan2
- KCNMA1 | c.3319G>A p.D1107N (on ENST00000286628 / NM_001161352.2; = p.D1049N on NM_002247.4) | Missense Mutation (SNP) | VAF 62/422 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as rs1314238418, COSV54278061; called by muse, mutect2, varscan2
- KCNQ1 | c.1699A>T p.I567F | Missense Mutation (SNP) | VAF 57/352 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as CM139863; called by mutect2, varscan2
- KCNU1 | c.1627G>T p.A543S | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV67755030; called by muse, mutect2
- KCNV2 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs745988476, COSV66057646; called by muse, mutect2, varscan2
- KIAA1210 | c.4565C>A p.S1522Y | Missense Mutation (SNP) | VAF 105/371 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV68179065; called by muse, mutect2, varscan2
- KIF18B | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs781011969, COSV59271080; called by muse, mutect2, varscan2
- KMT2A | c.2798G>T p.R933L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV63293572; called by muse, mutect2, varscan2
- KRT6A | c.1121T>C p.L374P | Missense Mutation (SNP) | VAF 64/563 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100416878; called by muse, mutect2, varscan2
- LARP4 | c.127T>C p.W43R | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1322986534, COSV53326283; called by muse, mutect2
- LCT | c.3758C>A p.T1253K | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV51549287; called by muse, mutect2
- LDHC | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV55005279, COSV99772718; called by muse, mutect2
- LEPR | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 12/357 reads (3%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs908449032; called by muse, mutect2
- LILRA6 | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV54440202; called by muse, mutect2, varscan2
- LILRB1 | c.929A>T p.Q310L (on ENST00000427581; = p.Q274L on NM_006669.6) | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs779387221; called by muse, mutect2, varscan2
- LIMD1 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199991743; called by muse, varscan2
- LPA | c.3804C>A p.S1268R | Missense Mutation (SNP) | VAF 97/751 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs758408377; called by muse, mutect2, varscan2
- LRRC7 | c.1915C>G p.P639A (on ENST00000651989 / NM_001370785.2; = p.P606A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV50448510; called by muse, mutect2
- LRRC7 | c.4376C>T p.A1459V (on ENST00000651989 / NM_001370785.2; = p.A1379V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/557 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.25); catalogued as rs931828859; called by muse, mutect2
- LRWD1 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.164); catalogued as rs1203394041; called by muse, mutect2, varscan2
- LYN | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.018); catalogued as COSV70206409; called by muse, mutect2, varscan2
- MAG | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs1245393323; called by muse, mutect2, varscan2
- MAGEB5 | c.28G>T p.G10* | Nonsense Mutation (SNP) | VAF 27/88 reads (31%) | catalogued as COSV66868652; called by muse, mutect2, varscan2
- MATN2 | c.917A>G p.Y306C | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs1490100134; called by muse, mutect2, varscan2
- MED13L | c.5371A>T p.S1791C | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs746735422; called by muse, mutect2, varscan2
- MED6 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1318353648; called by muse, mutect2, varscan2
- MEN1 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.916); catalogued as rs1455443205, COSV53642404, COSV53648870; called by muse, mutect2, varscan2
- MGAT5 | c.1101G>A p.W367* | Nonsense Mutation (SNP) | VAF 9/108 reads (8%) | catalogued as COSV99924919; called by muse, mutect2
- MMP12 | c.179T>C p.M60T | Missense Mutation (SNP) | VAF 97/449 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.258); catalogued as rs201266907; called by muse, mutect2, varscan2
- MMP16 | c.391C>A p.H131N | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV99691166; called by muse, mutect2
- MMP25 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755577652, COSV60678400; called by muse, mutect2, varscan2
- MNDA | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs200188147, COSV63741498; called by muse, mutect2, varscan2
- MRC2 | c.3104G>C p.W1035S | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57638429; called by muse, mutect2, varscan2
- MSGN1 | c.128C>G p.P43R | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs1233404257; called by muse, mutect2, varscan2
- MSR1 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100026970, COSV50513955; called by muse, mutect2, varscan2
- MTARC2 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 22/312 reads (7%) | catalogued as COSV63766014; called by muse, mutect2
- MTM1 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 16/187 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as CD991802; called by muse, mutect2
- MTSS1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 43/459 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs759492868, COSV100275828, COSV61500070; called by muse, mutect2
- MUC17 | c.5387C>T p.T1796I | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs145455751; called by muse, mutect2
- MUC5B | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs760039942; called by muse, mutect2, varscan2
- MUC5B | c.5969C>A p.T1990N | Missense Mutation (SNP) | VAF 58/581 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as rs768433230; called by muse, mutect2
- MYBPC1 | c.481+1G>A p.X161_splice (on ENST00000550270 / NM_206820.2; = p.X186_splice on NM_002465.4) | Splice Site (SNP) | VAF 49/379 reads (13%) | catalogued as rs112747330; called by muse, mutect2, varscan2
- MYH9 | c.5339G>A p.R1780Q | Missense Mutation (SNP) | VAF 52/397 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs760128307; called by muse, mutect2, varscan2
- MYO3A | c.2849G>A p.R950H | Missense Mutation (SNP) | VAF 60/652 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143371522, COSV56338758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAT10 | c.672G>T p.P224= | Splice Region (SNP) | VAF 43/154 reads (28%) | catalogued as COSV99139960; called by muse, mutect2, varscan2
- NFIA | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 67/593 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs867553973; called by muse, mutect2, varscan2
- NLRP8 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as rs145359925; called by muse, mutect2, varscan2
- NOX4 | c.1700G>C p.G567A | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV54457161; called by muse, mutect2, varscan2
- NPC1L1 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 19/154 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.061); catalogued as rs147224015; called by muse, mutect2, varscan2
- OBSCN | c.13150G>T p.E4384* | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as COSV52750931; called by muse, mutect2, varscan2
- ODF3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs771605747, COSV57293588; called by muse, mutect2, varscan2
- OPTC | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 69/670 reads (10%) | catalogued as rs1003793112; called by muse, mutect2
- OR10K1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 70/577 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as COSV56873963; called by muse, mutect2, varscan2
- OR13C2 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 45/500 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs149514294, COSV73377658; called by muse, mutect2
- OR4C6 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV58605929; called by muse, mutect2, varscan2
- OR52I1 | c.701C>A p.S234* | Nonsense Mutation (SNP) | VAF 38/376 reads (10%) | catalogued as COSV100331807; called by muse, mutect2
- OR5AC2 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100684402; called by muse, mutect2
- OR5M8 | c.485C>A p.T162N | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59116883; called by muse, mutect2, varscan2
- OR6C4 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 71/409 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs749394438, COSV67793096; called by muse, mutect2, varscan2
- OR8K5 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs774741509; called by muse, mutect2, varscan2
- PCDH10 | c.3055G>T p.D1019Y | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV52087894; called by muse, mutect2, varscan2
- PCDHGA6 | c.1886C>A p.A629E | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs778872651, COSV53960865; called by muse, mutect2, varscan2
- PCSK2 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV52731894; called by muse, mutect2, varscan2
- PCSK2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as rs188273152, COSV52727090; called by muse, mutect2, varscan2
- PDILT | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs144790154; called by muse, mutect2, varscan2
- PDPR | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV55349847; called by muse, mutect2
- PEAR1 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1157510043; called by muse, mutect2, varscan2
- PGK2 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59163629; called by muse, mutect2
- PGLYRP3 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 116/696 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV51950316; called by muse, mutect2, varscan2
- PIGU | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs150793656; called by muse, mutect2, varscan2
- PITPNM1 | c.2761C>T p.R921W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764146792; called by muse, mutect2, varscan2
- PLCH2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs371340812; called by muse, mutect2, varscan2
- PLEKHA1 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 50/538 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs140780715; called by muse, mutect2
- PLEKHO1 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs141878048; called by muse, mutect2, varscan2
- PLXNB3 | c.5170G>A p.A1724T | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377395548, COSV62795844; called by muse, mutect2, varscan2
- POLE | c.2599G>A p.V867I | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs374200895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLE | c.1183G>T p.G395W | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1475049831; called by muse, mutect2, varscan2
- POTEE | c.261C>A p.D87E | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.159); catalogued as rs564452394, COSV58236962, COSV58241247; called by muse, mutect2, varscan2
- PPP1R3A | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 58/493 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99492079; called by muse, mutect2, varscan2
- PPP4R3B | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); catalogued as rs1479002984; called by muse, mutect2, varscan2
- PRCC | c.890C>T p.T297I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs779113261, COSV54857450; called by muse, mutect2, varscan2
- PRKACG | c.101C>A p.P34H | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV99598562; called by muse, mutect2, varscan2
- PRPF40B | c.319C>T p.R107C (on ENST00000380281; = p.R101C on NM_012272.3) | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1219516882; called by muse, mutect2
- PSMA8 | c.19A>T p.R7W | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371585912; called by muse, mutect2, varscan2
- PTBP1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775074950, COSV62459301; called by muse, mutect2, varscan2
- PZP | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV54374341; called by muse, mutect2, varscan2
- RAPGEF1 | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs758806260, COSV64699274; called by muse, mutect2
- RAPSN | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs778113748, COSV100100331; called by muse, mutect2, varscan2
- RBP4 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 77/508 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs372010388; called by mutect2, varscan2
- REPS2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.042); catalogued as rs775458245; called by muse, mutect2, varscan2
- RERGL | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 54/316 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756331045; called by muse, mutect2, varscan2
- RIMBP2 | c.2677G>T p.G893* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | catalogued as COSV99900755; called by muse, mutect2, varscan2
- RIT2 | c.103+1G>T p.X35_splice | Splice Site (SNP) | VAF 36/255 reads (14%) | catalogued as rs761383716; called by muse, mutect2, varscan2
- RLF | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65651297; called by muse, mutect2
- RP1L1 | c.3095G>A p.S1032N | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV66752583; called by muse, mutect2, varscan2
- RTL4 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV61205737, COSV61206676; called by muse, mutect2, varscan2
- RUFY2 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100700070; called by muse, mutect2, varscan2
- RXRG | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as rs199523000; called by muse, mutect2, varscan2
- RYR1 | c.6310C>T p.R2104C | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as rs541757529, COSV62101310, COSV62103790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.8833G>A p.G2945S | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.186); catalogued as COSV63721922; called by muse, mutect2, varscan2
- RYR2 | c.12436G>A p.E4146K | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1349585791, CM045196, COSV63657666, COSV63700458; called by muse, mutect2, varscan2
- SALL1 | c.2332G>A p.A778T | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1441384433, COSV99177992; called by muse, mutect2, varscan2
- SCAF4 | c.3154C>T p.R1052C | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs758295971; called by muse, mutect2, varscan2
- SCN1A | c.2548G>C p.A850P (on ENST00000303395 / NM_001202435.3; = p.A839P on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/390 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV100320463, COSV57682879; called by muse, mutect2, varscan2
- SEC14L5 | c.1331G>A p.R444K | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV52036981; called by muse, mutect2, varscan2
- SEC16B | c.147del p.W49Cfs*67 | Frame Shift Del (DEL) | VAF 32/290 reads (11%) | catalogued as COSV100381785; called by mutect2, pindel, varscan2
- SLAMF6 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100924967, COSV63586604; called by muse, mutect2
- SLC10A3 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as rs782319797, COSV99682173; called by muse, mutect2, varscan2
- SLC12A3 | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 79/459 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM076522, COSV99344210; called by muse, mutect2, varscan2
- SLC20A2 | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100646016, COSV60602044; called by muse, mutect2, varscan2
- SLC20A2 | c.1285C>T p.R429C | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773208227, COSV60601637; called by muse, mutect2, varscan2
- SLC2A7 | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1386015467, COSV68902222; called by muse, mutect2
- SLC5A7 | c.1624C>A p.L542I | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV99886303; called by muse, mutect2
- SLC6A11 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.669); catalogued as COSV54390218; called by muse, mutect2, varscan2
- SLC6A17 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs1198247401, COSV58994659; called by muse, mutect2, varscan2
- SLIT1 | c.1528G>T p.D510Y | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV56586614; called by muse, mutect2, varscan2
- SLITRK1 | c.1943G>T p.R648L | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs377156560, COSV65675289; called by muse, mutect2, varscan2
- SMARCA2 | c.3818G>A p.R1273H | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61809894; called by muse, mutect2, varscan2
- SORCS3 | c.2584G>T p.G862W | Missense Mutation (SNP) | VAF 43/348 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100863869; called by muse, mutect2, varscan2
- SPAG5 | c.3354G>A p.E1118= | Splice Region (SNP) | VAF 23/165 reads (14%) | catalogued as rs1215207848; called by muse, mutect2, varscan2
- SPATA18 | c.1033G>T p.V345L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs754546637; called by muse, mutect2, varscan2
- SPO11 | c.633G>T p.R211= | Splice Region (SNP) | VAF 18/191 reads (9%) | catalogued as COSV61995167; called by muse, mutect2
- SPON1 | c.1260C>A p.D420E | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); catalogued as COSV59961695; called by muse, mutect2, varscan2
- SPRR3 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 63/472 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV54881265, COSV99768492; called by muse, varscan2
- SRPK3 | c.1262C>A p.T421K | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV54206323; called by muse, mutect2, varscan2
- SRRM1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 40/446 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs762320650, COSV60481118; called by muse, mutect2
- ST8SIA5 | c.507C>A p.N169K | Missense Mutation (SNP) | VAF 37/436 reads (8%) | PolyPhen possibly damaging (0.758); catalogued as COSV59334585; called by muse, mutect2
- STAB1 | c.6211C>T p.R2071C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs200633823, COSV100194431; called by mutect2, varscan2
- STK19 | c.1033G>A p.D345N (on ENST00000375333 / NM_032454.1; = p.D341N on NM_004197.1) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748479551, COSV64692985; called by mutect2, varscan2
- STX4 | c.705G>C p.G235= | Splice Region (SNP) | VAF 6/119 reads (5%) | catalogued as rs1567391133; called by muse, mutect2
- TAF4B | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 50/376 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs745752584; called by muse, mutect2, varscan2
- TAS1R1 | c.1055G>T p.C352F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.894); catalogued as COSV59839677; called by muse, mutect2, varscan2
- TBX3 | c.1579A>G p.M527V (on ENST00000257566 / NM_016569.4; = p.M507V on NM_005996.4) | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs936879280; called by muse, mutect2, varscan2
- TMEM108 | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs375774878; called by muse, mutect2, varscan2
- TMEM132A | c.552C>A p.C184* | Nonsense Mutation (SNP) | VAF 40/244 reads (16%) | catalogued as rs763429462, COSV50014906; called by muse, mutect2, varscan2
- TNIK | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 52/211 reads (25%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.056); catalogued as rs375320513, COSV99455841; called by muse, mutect2, varscan2
- TNN | c.1925C>T p.P642L | Missense Mutation (SNP) | VAF 59/460 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs778962849; called by muse, mutect2, varscan2
- TNNI3K | c.2161G>T p.E721* | Nonsense Mutation (SNP) | VAF 26/221 reads (12%) | catalogued as rs1035914333; called by muse, mutect2, varscan2
- TNXB | c.10075G>A p.G3359R (on ENST00000647633; = p.G3112R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.388); catalogued as rs760099672; called by muse, mutect2, varscan2
- TNXB | c.9064G>T p.G3022W (on ENST00000647633; = p.G2775W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770521692, COSV100926058, COSV64474629; called by mutect2, varscan2
- TNXB | c.6100G>A p.V2034M (on ENST00000647633; = p.V1787M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs548921928, COSV64482350; called by muse, mutect2
- TRIM22 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV66091458; called by muse, mutect2, varscan2
- TRIOBP | c.5260G>A p.G1754R | Missense Mutation (SNP) | VAF 45/281 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1182991728; called by muse, mutect2, varscan2
- TRPA1 | c.483A>T p.E161D | Missense Mutation (SNP) | VAF 33/446 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as COSV51562575; called by muse, mutect2
- TRPM8 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1434711135; called by muse, mutect2, varscan2
- TTC21B | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1437304335, CM1514717, COSV54636319; ClinVar: uncertain significance; called by muse, mutect2
- TTC31 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs528341055, COSV52036143; called by muse, mutect2
- TUBB8B | c.771G>T p.M257I | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.302); catalogued as rs1184400610; called by muse, mutect2, varscan2
- UBQLN4 | c.1030G>T p.G344W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64148958; called by muse, mutect2, varscan2
- VAC14 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356562230; called by muse, mutect2, varscan2
- VCAN | c.1930C>A p.P644T | Missense Mutation (SNP) | VAF 69/366 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV99426729; called by muse, mutect2, varscan2
- VEGFC | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99710579; called by muse, mutect2, varscan2
- WASHC2A | c.3547G>T p.D1183Y | Missense Mutation (SNP) | VAF 148/1038 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451456135; called by muse, mutect2, varscan2
- WSCD2 | c.615C>A p.S205R | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV99774193; called by muse, mutect2, varscan2
- ZBTB17 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746467058, COSV100998983; called by muse, mutect2, varscan2
- ZCCHC14 | c.2749C>T p.R917C (on ENST00000268616; = p.R1054C on NM_015144.3) | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761891613, COSV51887001; called by muse, mutect2, varscan2
- ZEB2 | c.961C>A p.H321N | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100355034; called by muse, mutect2, varscan2
- ZFHX4 | c.1371C>A p.N457K | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.203); catalogued as rs547602121, COSV99261831; called by muse, mutect2, varscan2
- ZIM2 | c.1321C>G p.P441A | Missense Mutation (SNP) | VAF 43/423 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV55628630; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2297G>C p.R766P | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV99080345; called by muse, mutect2, varscan2
- ZNF208 | c.3662G>T p.G1221V | Missense Mutation (SNP) | VAF 51/403 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs780050434; called by muse, mutect2, varscan2
- ZNF217 | c.2924C>T p.S975F | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs1439945173; called by muse, mutect2, varscan2
- ZNF276 | c.1384G>A p.V462I (on ENST00000443381 / NM_001113525.2; = p.V387I on NM_152287.4) | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as rs199868546; called by muse, mutect2, varscan2
- ZNF536 | c.1264G>T p.A422S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.368); catalogued as rs1391146838; called by muse, mutect2, varscan2
- ZNF667 | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs201561717; called by muse, mutect2
- ZNF775 | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.837); catalogued as rs1256063033; called by muse, mutect2, varscan2
- ZNF835 | c.1437C>A p.C479* | Nonsense Mutation (SNP) | VAF 36/192 reads (19%) | catalogued as COSV73379375; called by muse, mutect2, varscan2
- ZNF836 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.987); catalogued as COSV59085491; called by muse, mutect2, varscan2
- ZNF92 | c.719G>A p.R240Q (on ENST00000328747 / NM_152626.4; = p.R171Q on NM_007139.4) | Missense Mutation (SNP) | VAF 82/415 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs878923923, COSV60876012; called by muse, mutect2, varscan2
- ZP4 | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 63/341 reads (18%) | catalogued as COSV100850609, COSV63910850; called by muse, mutect2, varscan2
- ZSWIM9 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs913823772, COSV100167822; called by muse, mutect2, varscan2
- AAK1 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- AASS | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2
- ABCA13 | c.10721T>G p.L3574R | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCC8 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 58/381 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABI3BP | c.2222C>A p.S741* | Nonsense Mutation (SNP) | VAF 60/487 reads (12%) | called by muse, mutect2, varscan2
- AC011005.1 | c.714G>T p.L238F | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ACSM3 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 37/371 reads (10%) | called by muse, mutect2
- ACSM3 | c.256A>T p.I86F | Missense Mutation (SNP) | VAF 37/360 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- ADAM12 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2
- ADAMTS6 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 52/278 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- ADGRA2 | c.3695del p.G1232Afs*71 | Frame Shift Del (DEL) | VAF 17/138 reads (12%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.1007G>C p.C336S | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB3 | c.1593C>A p.D531E | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRG7 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 40/257 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, varscan2
- ADGRL4 | c.1912G>A p.V638I | Missense Mutation (SNP) | VAF 15/376 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.123); called by muse, mutect2
- ADH1B | c.958T>C p.Y320H | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by mutect2, varscan2
- ADM | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AIFM2 | c.178+2T>C p.X60_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- AL353579.1 | c.376del p.Q126Kfs*43 | Frame Shift Del (DEL) | VAF 49/356 reads (14%) | called by mutect2, pindel, varscan2
- ALDH2 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 53/275 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALOXE3 | c.800A>T p.H267L | Missense Mutation (SNP) | VAF 16/305 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); called by muse, mutect2
- ALPK3 | c.3973G>C p.D1325H | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AMELX | c.570+1G>T p.X190_splice | Splice Site (SNP) | VAF 95/521 reads (18%) | called by muse, mutect2, varscan2
- ANGPTL1 | c.1386C>A p.S462R | Missense Mutation (SNP) | VAF 47/495 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD12 | c.2903A>T p.E968V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ANKRD30B | c.3709C>A p.Q1237K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by mutect2, varscan2
- ANKS1B | c.3356C>A p.A1119E (on ENST00000547776 / NM_152788.4; = p.A285E on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANO2 | c.2838C>G p.F946L (on ENST00000356134 / NM_001278597.3; = p.F950L on NM_001278596.3) | Missense Mutation (SNP) | VAF 57/491 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ANXA8 | c.927dup p.D310Rfs*5 | Frame Shift Ins (INS) | VAF 77/699 reads (11%) | called by mutect2, pindel, varscan2
- APLNR | c.910C>A p.L304I | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APMAP | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 34/203 reads (17%) | called by muse, mutect2, varscan2
- APOBR | c.1694C>A p.T565N (on ENST00000431282; = p.T574N on NM_018690.4) | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2
- ARMCX3 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARNT2 | c.1388A>T p.Q463L | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- ATAD3A | c.233C>G p.A78G | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- ATP13A1 | c.1795G>T p.D599Y | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- ATXN1L | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 69/462 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- BACH2 | c.1691C>A p.P564Q | Missense Mutation (SNP) | VAF 59/352 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BAX | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEND2 | c.1403C>A p.S468* | Nonsense Mutation (SNP) | VAF 35/236 reads (15%) | called by muse, mutect2, varscan2
- BEX5 | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2
- BOLL | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- BTBD9 | c.290C>G p.T97S | Missense Mutation (SNP) | VAF 20/513 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.096); called by muse, mutect2
- C16orf71 | c.1256C>A p.A419E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, varscan2
- C16orf90 | c.298G>A p.G100S (on ENST00000399645 / NM_001353385.2; = p.G91S on NM_001080524.2) | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.067); called by muse, mutect2
- C1QC | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- C20orf204 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- C6orf141 | c.161C>A p.A54E | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.17); called by muse, mutect2
- CACNA1E | c.4718G>C p.S1573T | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CACNA1E | c.4822C>A p.P1608T | Missense Mutation (SNP) | VAF 61/332 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1S | c.1620-1G>T p.X540_splice | Splice Site (SNP) | VAF 42/184 reads (23%) | called by muse, mutect2, varscan2
- CAPN15 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CASS4 | c.1442G>T p.R481M | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, varscan2
- CBLN3 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC146 | c.519del p.K174Rfs*2 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- CCDC168 | c.7438G>T p.E2480* | Nonsense Mutation (SNP) | VAF 28/226 reads (12%) | called by muse, mutect2, varscan2
- CCDC60 | c.909dup p.R304Sfs*31 | Frame Shift Ins (INS) | VAF 36/267 reads (13%) | called by mutect2, pindel, varscan2
- CCDC87 | c.1903C>T p.Q635* | Nonsense Mutation (SNP) | VAF 29/210 reads (14%) | called by muse, mutect2, varscan2
- CCDC96 | c.834dup p.E279Rfs*89 | Frame Shift Ins (INS) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- CCT7 | c.918G>T p.R306S | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CD163 | c.3026C>A p.P1009H | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CD7 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.054); called by muse, mutect2
- CDC27 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDIPT | c.551dup p.L184Ffs*57 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | called by mutect2, pindel
- CDK17 | c.971A>T p.K324I | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CDK20 | c.730G>T p.E244* (on ENST00000325303 / NM_001039803.3; = p.E223* on NM_012119.4) | Nonsense Mutation (SNP) | VAF 40/222 reads (18%) | called by muse, mutect2, varscan2
- CEP192 | c.5149A>T p.K1717* | Nonsense Mutation (SNP) | VAF 38/322 reads (12%) | called by muse, mutect2, varscan2
- CEP192 | c.5150A>T p.K1717M | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CEP41 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 79/636 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP54 | c.9025C>A p.P3009T | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.325); called by muse, mutect2
- CHAD | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.73); called by muse, mutect2
- CHD4 | c.1153G>T p.D385Y (on ENST00000357008 / NM_001363606.2; = p.D398Y on NM_001273.5) | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CHL1 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.298); called by muse, mutect2
- CHM | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CKAP2 | c.928A>T p.R310* (on ENST00000378037 / NM_001098525.2; = p.R309* on NM_018204.5) | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- CNFN | c.19A>C p.S7R | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2
- CNNM1 | c.1025G>T p.C342F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTNAP5 | c.633C>A p.S211R | Missense Mutation (SNP) | VAF 80/560 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTRL | c.1468G>T p.G490W | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- COL12A1 | c.2122G>T p.G708C | Missense Mutation (SNP) | VAF 44/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL21A1 | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A5 | c.3430C>T p.L1144F | Missense Mutation (SNP) | VAF 148/603 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CPT1A | c.2029G>T p.V677F | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CRB2 | c.3100G>T p.A1034S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.029); called by muse, mutect2
- CRCT1 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 32/216 reads (15%) | PolyPhen possibly damaging (0.74); called by muse, varscan2
- CRYBG3 | c.5947G>T p.G1983* | Nonsense Mutation (SNP) | VAF 11/135 reads (8%) | called by muse, mutect2
- CT47B1 | c.517C>G p.Q173E | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- CX3CR1 | c.609_610del p.L204Afs*27 | Frame Shift Del (DEL) | VAF 43/346 reads (12%) | called by mutect2, pindel, varscan2
- DACT3 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.033); called by muse, mutect2
- DCAF12L1 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- DDI1 | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DDN | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DENND4B | c.4417C>A p.H1473N | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- DENND5B | c.1805G>T p.R602M | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- DES | c.955C>A p.Q319K | Missense Mutation (SNP) | VAF 105/459 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- DGKB | c.2178G>T p.M726I | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- DGKB | c.1378C>G p.Q460E | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- DHX35 | c.1135G>T p.V379L | Missense Mutation (SNP) | VAF 88/482 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DISC1 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DMBX1 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH11 | c.8030G>T p.R2677M | Missense Mutation (SNP) | VAF 80/481 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DNAH9 | c.4389C>A p.C1463* | Nonsense Mutation (SNP) | VAF 69/253 reads (27%) | called by muse, mutect2, varscan2
- DPP6 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2
- DPY19L4 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DTHD1 | c.1169G>C p.C390S (on ENST00000456874; = p.C225S on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- DYSF | c.137G>T p.W46L | Missense Mutation (SNP) | VAF 57/469 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFL1 | c.2837G>T p.G946V | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- EGFR | c.2957G>C p.R986T | Missense Mutation (SNP) | VAF 60/440 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- EIF2AK3 | c.2281C>G p.L761V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.07); called by muse, mutect2
- EIF5AL1 | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 50/430 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- EOMES | c.340C>A p.L114M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- EPS8L3 | c.1727C>A p.P576Q (on ENST00000361965 / NM_133181.4; = p.P546Q on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- F13A1 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 72/450 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM170A | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- FAM170B | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM47A | c.1118C>A p.S373Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- FAT4 | c.14491C>A p.P4831T | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAU | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 15/270 reads (6%) | called by muse, mutect2
- FBRSL1 | c.2776C>T p.R926C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by mutect2, varscan2
- FBXL7 | c.617C>A p.T206N | Missense Mutation (SNP) | VAF 90/534 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FBXO39 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBXO47 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FHDC1 | c.3209G>T p.R1070M | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- FHOD3 | c.2661C>G p.F887L (on ENST00000359247 / NM_001281739.3; = p.F904L on NM_025135.5) | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- FLG | c.4180C>A p.Q1394K | Missense Mutation (SNP) | VAF 95/622 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- FLOT1 | c.755A>C p.Q252P | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FMN2 | c.2285G>T p.G762V | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- FNDC1 | c.5432G>A p.S1811N | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FOXF2 | c.1301G>A p.S434N | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GAD2 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GALC | c.1077del p.T360Qfs*5 | Frame Shift Del (DEL) | VAF 60/406 reads (15%) | called by mutect2, pindel, varscan2
- GBE1 | c.1783G>C p.G595R | Missense Mutation (SNP) | VAF 42/324 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GBP1 | c.1267A>G p.K423E | Missense Mutation (SNP) | VAF 103/751 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- GCGR | c.460G>T p.G154W | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- GCN1 | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2, varscan2
- GDF5 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GNGT1 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GPS1 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 9/187 reads (5%) | called by muse, mutect2
- GSK3A | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- GZMA | c.654C>G p.C218W | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HARBI1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 30/224 reads (13%) | called by muse, mutect2, varscan2
- HAS1 | c.438C>A p.D146E | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HCN4 | c.1735G>T p.E579* | Nonsense Mutation (SNP) | VAF 53/157 reads (34%) | called by muse, varscan2
- HDAC9 | c.74G>T p.R25M | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HEMGN | c.257T>A p.V86E | Missense Mutation (SNP) | VAF 20/283 reads (7%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.49); called by muse, mutect2
- HIVEP2 | c.4252G>T p.E1418* | Nonsense Mutation (SNP) | VAF 55/308 reads (18%) | called by muse, mutect2, varscan2
- HOGA1 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HS3ST2 | c.900C>A p.D300E | Missense Mutation (SNP) | VAF 45/422 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HS3ST4 | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.74); called by muse, mutect2
- IGKV1-8 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 65/499 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- IL1R1 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ILDR2 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- INPP5D | c.3445del p.A1149Rfs*35 (on ENST00000445964 / NM_001017915.3; = p.A1148Rfs*35 on NM_005541.5) | Frame Shift Del (DEL) | VAF 19/171 reads (11%) | called by mutect2, pindel, varscan2
- IQGAP1 | c.3844G>A p.D1282N | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IQGAP2 | c.2473C>A p.L825M | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ITGB8 | c.888G>T p.L296F | Missense Mutation (SNP) | VAF 42/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNA4 | c.1595C>A p.P532H | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH6 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNJ6 | c.748G>T p.G250W | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNV1 | c.1472G>A p.R491K | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KDR | c.2782C>G p.L928V | Missense Mutation (SNP) | VAF 90/825 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDR | c.1868A>T p.D623V | Missense Mutation (SNP) | VAF 253/602 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KERA | c.996C>G p.I332M | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- KIAA0319L | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- KIR2DL3 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 52/392 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, varscan2
- KLF4 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- KNL1 | c.6282G>C p.E2094D (on ENST00000346991 / NM_170589.5; = p.E2068D on NM_144508.5) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.42); called by muse, mutect2
- KRT5 | c.1520G>T p.G507V | Missense Mutation (SNP) | VAF 44/362 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- KRT73 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, varscan2
- KRTAP4-7 | c.314G>C p.C105S | Missense Mutation (SNP) | VAF 95/433 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- LARGE2 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.205); called by muse, mutect2
- LAX1 | c.288G>T p.L96F | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LCE1D | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 55/402 reads (14%) | PolyPhen benign (0.326); called by muse, mutect2, varscan2
- LEXM | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LGR5 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LILRA6 | c.1301C>A p.S434Y | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2
- LIPG | c.747G>T p.Q249H | Missense Mutation (SNP) | VAF 61/425 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC4C | c.331C>A p.H111N | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- LRRC7 | c.4230G>C p.K1410N (on ENST00000651989 / NM_001370785.2; = p.K1330N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LRSAM1 | c.492A>T p.R164S | Missense Mutation (SNP) | VAF 64/418 reads (15%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- LYAR | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LYRM9 | c.107A>T p.Y36F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MACF1 | c.13834A>G p.M4612V (on ENST00000372915; = p.M2545V on NM_012090.5) | Missense Mutation (SNP) | VAF 69/308 reads (22%) | called by muse, mutect2, varscan2
- MACO1 | c.1531A>G p.R511G | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MANSC1 | c.137C>A p.S46Y | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MAP2 | c.2357G>T p.C786F | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2
- MAPK6 | c.1556G>A p.R519K | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARCO | c.767-1G>T p.X256_splice | Splice Site (SNP) | VAF 32/346 reads (9%) | called by muse, mutect2
- MASP1 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 28/536 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- MBL2 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.212); called by muse, mutect2
- MC3R | c.635T>A p.L212H | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MED12L | c.3863T>A p.L1288Q | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MELK | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- MFAP1 | c.858A>C p.R286S | Missense Mutation (SNP) | VAF 5/130 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MGA | c.6400T>G p.F2134V (on ENST00000219905 / NM_001164273.1; = p.F1925V on NM_001080541.2) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MGA | c.7140-1G>T p.X2380_splice (on ENST00000219905 / NM_001164273.1; = p.X2171_splice on NM_001080541.2) | Splice Site (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- MIOS | c.1764G>T p.L588F | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- MISP | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MLIP | c.618C>A p.Y206* | Nonsense Mutation (SNP) | VAF 49/288 reads (17%) | called by muse, mutect2, varscan2
- MMP3 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MRC2 | c.2147G>T p.S716I | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MRC2 | c.3945G>T p.W1315C | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH9 | c.1809G>T p.Q603H | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- MTRNR2L10 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 43/220 reads (20%) | PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MUC16 | c.23521G>C p.G7841R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC16 | c.17956G>T p.A5986S | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUC19 | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- MUC19 | c.217-1G>T p.X73_splice | Splice Site (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- MXRA5 | c.6286C>A p.H2096N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO18A | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEB | c.2521G>C p.D841H | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NGFR | c.492C>A p.C164* | Nonsense Mutation (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- NKX3-2 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- NLGN2 | c.2047G>T p.G683C | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP13 | c.3083T>A p.L1028Q | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP2 | c.2135G>T p.S712I | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- NLRP3 | c.2287C>G p.L763V | Missense Mutation (SNP) | VAF 81/501 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- NLRP5 | c.3118C>G p.Q1040E | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- NMNAT2 | c.261C>A p.C87* | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- NPAP1 | c.2428G>T p.A810S | Missense Mutation (SNP) | VAF 66/296 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- NPR3 | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- NTNG1 | c.525T>A p.Y175* | Nonsense Mutation (SNP) | VAF 36/234 reads (15%) | called by muse, mutect2, varscan2
- OAS3 | c.3252+1del | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | called by mutect2, pindel
- OR10A2 | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 59/536 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR10H1 | c.513C>A p.H171Q | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- OR10H2 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by muse, mutect2
- OR10J3 | c.319A>T p.T107S | Missense Mutation (SNP) | VAF 50/426 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- OR10W1 | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- OR13A1 | c.195G>T p.L65F | Missense Mutation (SNP) | VAF 73/486 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR2D3 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2F2 | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2L3 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, varscan2
- OR51B2 | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- OR51G2 | c.614T>C p.M205T | Missense Mutation (SNP) | VAF 31/323 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- OR52K1 | c.209C>A p.T70N | Missense Mutation (SNP) | VAF 73/490 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR6C70 | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); called by muse, varscan2
- OR7E24 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8J1 | c.575C>A p.T192N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR9G1 | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 45/716 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.603); called by muse, mutect2
- OTOF | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- OTOGL | c.2469G>C p.Q823H (on ENST00000547103; = p.Q814H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT tolerated (0.82); PolyPhen benign (0.212); called by muse, mutect2
- PARPBP | c.667-1G>T p.X223_splice | Splice Site (SNP) | VAF 45/323 reads (14%) | called by muse, mutect2, varscan2
- PCDHB13 | c.1302G>T p.Q434H | Missense Mutation (SNP) | VAF 59/290 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PCDHB5 | c.2326C>A p.Q776K | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHGA3 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHGA3 | c.1264C>A p.L422M | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- PCLO | c.14650T>G p.S4884A | Missense Mutation (SNP) | VAF 101/705 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PCSK5 | c.4350G>T p.M1450I | Missense Mutation (SNP) | VAF 61/398 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEG3 | c.812A>T p.Q271L | Missense Mutation (SNP) | VAF 56/463 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PIWIL4 | c.253A>T p.I85F | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PLCB4 | c.974G>T p.S325I | Missense Mutation (SNP) | VAF 63/494 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PLEK | c.1027C>A p.Q343K | Missense Mutation (SNP) | VAF 44/365 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- PLOD3 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLPPR4 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PLTP | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA3 | c.4638G>T p.E1546D | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNA3 | c.4639G>T p.D1547Y | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLR2F | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- POM121L12 | c.405C>G p.S135R | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- POSTN | c.441T>C p.S147= | Splice Region (SNP) | VAF 29/153 reads (19%) | called by muse, mutect2, varscan2
- POU3F3 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP2R5B | c.497A>T p.Q166L | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- PPP4R3C | c.2368A>T p.S790C | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- PRAMEF2 | c.476_477insA p.Q160Pfs*3 | Frame Shift Ins (INS) | VAF 30/264 reads (11%) | called by mutect2, varscan2
- PRAMEF2 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- PRKCG | c.830T>A p.L277* | Nonsense Mutation (SNP) | VAF 16/410 reads (4%) | called by muse, mutect2
- PRR14 | c.743del p.P248Rfs*33 | Frame Shift Del (DEL) | VAF 22/143 reads (15%) | called by mutect2, pindel, varscan2
- PRR15 | c.186del p.N63Ifs*27 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- PRRC2A | c.4436C>T p.A1479V | Missense Mutation (SNP) | VAF 49/345 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PTK2 | c.2710-3C>T | Splice Region (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- PTPRN | c.496G>T p.G166* | Nonsense Mutation (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- PTPRQ | c.6985G>A p.E2329K (on ENST00000616559; = p.E2296K on NM_001145026.2) | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPRT | c.1301A>G p.Q434R | Missense Mutation (SNP) | VAF 60/619 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- PTPRZ1 | c.1665del p.T556Lfs*5 | Frame Shift Del (DEL) | VAF 18/174 reads (10%) | called by mutect2, pindel, varscan2
- PXDN | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- QARS1 | c.916A>T p.N306Y | Missense Mutation (SNP) | VAF 64/395 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- QSER1 | c.1138G>T p.G380W (on ENST00000399302; = p.G509W on NM_001076786.3) | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- RAD51AP2 | c.1761G>C p.L587F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2
- RASL11B | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 43/388 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- RBL1 | c.1669A>T p.S557C | Missense Mutation (SNP) | VAF 39/303 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- RBP3 | c.2452T>A p.S818T | Missense Mutation (SNP) | VAF 18/468 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.315); called by muse, mutect2
- REG3G | c.16G>C p.A6P | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- REG4 | c.289C>A p.H97N | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RET | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- REXO1 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RHPN2 | c.1193C>A p.T398K | Missense Mutation (SNP) | VAF 26/812 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); called by muse, mutect2
- RIT2 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNPEP | c.1766G>T p.W589L | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RP1 | c.2504C>A p.P835Q | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RPL10L | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RUFY3 | c.697-2A>T p.X233_splice | Splice Site (SNP) | VAF 10/173 reads (6%) | called by muse, mutect2
- RYR1 | c.7204C>G p.R2402G | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.489); called by muse, mutect2
- RYR2 | c.7652C>A p.T2551N | Missense Mutation (SNP) | VAF 75/459 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SAGE1 | c.1658C>A p.T553N | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- SARS2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SASH3 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SCAF8 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SCN2A | c.89C>A p.A30E | Missense Mutation (SNP) | VAF 76/756 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, mutect2
- SDCBP | c.131-1G>C p.X44_splice | Splice Site (SNP) | VAF 10/171 reads (6%) | called by muse, mutect2
- SDK1 | c.4230G>T p.G1410= | Splice Region (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- SEC14L4 | c.1025A>T p.Y342F | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- SEMA3A | c.1191T>A p.D397E | Missense Mutation (SNP) | VAF 44/371 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SEPTIN14 | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 18/545 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- SFT2D3 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SH2B1 | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SIGLEC6 | c.28T>A p.S10T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SIN3A | c.3529G>T p.V1177L | Missense Mutation (SNP) | VAF 80/528 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SIPA1L3 | c.5236G>T p.V1746L | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- SLC18A3 | c.1130G>T p.C377F | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC19A3 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 82/429 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC26A11 | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- SLC47A2 | c.1258T>C p.F420L | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.158); called by muse, mutect2
- SLC6A4 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- SORCS3 | c.2585G>T p.G862V | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX5 | c.2178A>G p.I726M | Missense Mutation (SNP) | VAF 118/543 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX7 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- SPAG17 | c.3442G>T p.D1148Y | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SPATA31A6 | c.176dup p.G60Wfs*26 | Frame Shift Ins (INS) | VAF 220/1025 reads (21%) | called by mutect2, pindel, varscan2
- SPATA6 | c.1398G>T p.M466I | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- SPTA1 | c.2319C>A p.C773* | Nonsense Mutation (SNP) | VAF 77/694 reads (11%) | called by muse, mutect2, varscan2
- SRRM4 | c.632C>A p.P211H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ST8SIA6 | c.636-1G>T p.X212_splice | Splice Site (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2
- STAC | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STEAP3 | c.217C>T p.Q73* | Nonsense Mutation (SNP) | VAF 38/181 reads (21%) | called by muse, mutect2, varscan2
- SYN3 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYT9 | c.590G>T p.R197I | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- TAOK3 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TAS1R2 | c.2129C>A p.P710H | Missense Mutation (SNP) | VAF 80/514 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TBC1D31 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TBC1D32 | c.3255C>G p.F1085L | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TECRL | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TF | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 71/292 reads (24%) | called by muse, mutect2, varscan2
- TFAP2B | c.601+1G>T p.X201_splice | Splice Site (SNP) | VAF 57/432 reads (13%) | called by muse, mutect2, varscan2
- TFAP2D | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 93/418 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- TIAM2 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TIMELESS | c.923G>T p.S308I | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- TMEM185A | c.685-1G>T p.X229_splice | Splice Site (SNP) | VAF 20/233 reads (9%) | called by muse, mutect2
- TMEM19 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM59L | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- TNFSF15 | c.431C>A p.S144* | Nonsense Mutation (SNP) | VAF 51/281 reads (18%) | called by muse, mutect2, varscan2
- TNN | c.2015G>T p.S672I | Missense Mutation (SNP) | VAF 76/522 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TNN | c.2465C>A p.A822D | Missense Mutation (SNP) | VAF 32/403 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TNRC18 | c.2552G>T p.R851M | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TONSL | c.4129C>T p.R1377C | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- TPTE | c.802G>T p.V268L (on ENST00000618007 / NM_199261.4; = p.V250L on NM_199259.4) | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, mutect2
- TRAPPC12 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TRBV28 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TRIM25 | c.1615G>T p.E539* | Nonsense Mutation (SNP) | VAF 48/264 reads (18%) | called by muse, mutect2, varscan2
- TRIM42 | c.1620G>T p.L540F | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- TRIM61 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- TRIM65 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRMT44 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- TRRAP | c.10904G>A p.R3635H (on ENST00000359863 / NM_001244580.1; = p.R3606H on NM_003496.3) | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2
- TSHZ2 | c.1731del p.I578Lfs*7 | Frame Shift Del (DEL) | VAF 39/248 reads (16%) | called by mutect2, pindel, varscan2
- TSPAN18 | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 42/403 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTC5 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2
- UNC5D | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- UNC80 | c.4982G>T p.R1661L | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- URI1 | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- USH2A | c.2077C>A p.P693T | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- USP26 | c.529C>A p.H177N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP5 | c.1928G>C p.C643S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- VN1R2 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 24/220 reads (11%) | PolyPhen benign (0.184); called by muse, mutect2, varscan2
- WDR6 | c.2284G>C p.G762R | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- WDR91 | c.1876G>T p.G626W | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- WDR97 | c.2315G>T p.R772L | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- XAB2 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- XCR1 | c.663C>A p.H221Q | Missense Mutation (SNP) | VAF 46/264 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- ZBED1 | c.1531G>T p.G511C | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- ZBTB4 | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- ZFHX4 | c.601del p.L201Sfs*17 | Frame Shift Del (DEL) | VAF 36/329 reads (11%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.1891C>A p.H631N | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZFHX4 | c.7226C>A p.P2409H | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ZFP37 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.009); called by muse, mutect2
- ZFYVE9 | c.3034G>T p.V1012L | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2
- ZIM2 | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.417); called by muse, mutect2
- ZIM3 | c.926G>T p.C309F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIM3 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZNF492 | c.511T>C p.C171R | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF773 | c.1313C>A p.T438N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- ZNF793 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF804B | c.48C>A p.H16Q | Missense Mutation (SNP) | VAF 36/257 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF880 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- ZNRF4 | c.791T>A p.L264Q | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ZSCAN2 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCB5 | c.1341G>T p.V447= (on ENST00000404938 / NM_001163941.2; = p.V2= on NM_178559.6) | Silent (SNP) | VAF 36/256 reads (14%) | called by muse, mutect2, varscan2
- ABCG8 | c.132C>T p.P44= | Silent (SNP) | VAF 52/274 reads (19%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.744G>T p.G248= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- ADCY2 | c.993C>T p.C331= | Silent (SNP) | VAF 47/276 reads (17%) | catalogued as rs775853444; called by muse, mutect2, varscan2
- ADGRB1 | c.3942G>A p.A1314= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs746758009; called by muse, mutect2, varscan2
- ADGRB3 | c.2655T>C p.S885= | Silent (SNP) | VAF 37/348 reads (11%) | called by muse, varscan2
- AKAP9 | c.3588T>C p.S1196= | Silent (SNP) | VAF 20/548 reads (4%) | called by muse, mutect2
- AL121899.2 | c.621C>A p.I207= | Silent (SNP) | VAF 42/242 reads (17%) | called by muse, mutect2, varscan2
- ALDH1A3 | c.270G>T p.R90= | Silent (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- ALG10 | c.33C>G p.A11= | Silent (SNP) | VAF 44/326 reads (13%) | called by muse, mutect2, varscan2
- ANGPT4 | c.864C>T p.F288= | Silent (SNP) | VAF 30/189 reads (16%) | catalogued as COSV67920620; called by muse, mutect2, varscan2
- ANK1 | c.1728C>T p.A576= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs189710010; ClinVar: likely benign; called by mutect2, varscan2
- APOL5 | c.816G>A p.T272= | Silent (SNP) | VAF 67/381 reads (18%) | catalogued as rs370593513; called by muse, mutect2, varscan2
- AQP10 | c.687C>T p.G229= | Silent (SNP) | VAF 31/221 reads (14%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.1515G>A p.E505= | Silent (SNP) | VAF 30/322 reads (9%) | called by muse, mutect2
- ARHGAP36 | c.618G>T p.L206= | Silent (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- ARHGAP44 | c.1881C>T p.G627= | Silent (SNP) | VAF 26/164 reads (16%) | catalogued as rs369980153; called by muse, mutect2, varscan2
- ARL13B | c.363G>A p.S121= | Silent (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- ARMCX2 | c.1710C>T p.A570= | Silent (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- ASCL1 | c.486G>T p.S162= | Silent (SNP) | VAF 48/260 reads (18%) | called by muse, mutect2, varscan2
- ASXL3 | c.2052C>A p.S684= | Silent (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- ASXL3 | c.2499G>C p.L833= | Silent (SNP) | VAF 104/646 reads (16%) | catalogued as COSV52471167, COSV99325348; called by muse, mutect2, varscan2
- ATP10D | c.402C>T p.I134= | Silent (SNP) | VAF 25/310 reads (8%) | catalogued as rs749516555, COSV99906092; called by muse, mutect2
- ATP13A1 | c.2973G>T p.L991= | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- BLZF1 | c.822C>G p.S274= | Silent (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2
- BRDT | c.2283C>A p.P761= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100746129; called by muse, mutect2, varscan2
- C10orf95 | c.391C>A p.R131= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- C9 | c.681C>A p.I227= | Silent (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- CA3 | c.96G>A p.E32= | Silent (SNP) | VAF 27/361 reads (7%) | called by muse, mutect2
- CACNA1B | c.3897T>A p.I1299= | Silent (SNP) | VAF 19/216 reads (9%) | called by muse, mutect2, varscan2
- CARD14 | c.1554A>T p.A518= | Silent (SNP) | VAF 30/163 reads (18%) | called by muse, mutect2, varscan2
- CASP5 | c.819C>A p.I273= | Silent (SNP) | VAF 117/678 reads (17%) | called by muse, mutect2, varscan2
- CATSPERG | c.3003C>T p.H1001= | Silent (SNP) | VAF 33/220 reads (15%) | catalogued as rs150283647; called by muse, mutect2, varscan2
- CCDC74B | c.840C>T p.R280= | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as rs765916236, COSV100134687; called by muse, mutect2, varscan2
- CDH12 | c.27G>T p.L9= | Silent (SNP) | VAF 47/317 reads (15%) | called by muse, mutect2, varscan2
- CEMIP | c.1626G>A p.T542= | Silent (SNP) | VAF 106/600 reads (18%) | catalogued as rs143318876; called by muse, mutect2, varscan2
- CFAP54 | c.2097G>T p.G699= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2, varscan2
- COL4A2 | c.600C>A p.R200= | Silent (SNP) | VAF 32/564 reads (6%) | catalogued as COSV64626844; called by muse, mutect2
- COL6A3 | c.3891C>T p.N1297= | Silent (SNP) | VAF 112/382 reads (29%) | catalogued as rs200722316, COSV55081933; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPNE6 | c.1146G>A p.P382= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs778192102, COSV53743123; called by muse, mutect2, varscan2
- CRACD | c.1929C>A p.G643= | Silent (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- CSMD2 | c.4764C>T p.Y1588= | Silent (SNP) | VAF 37/346 reads (11%) | catalogued as rs771004287, COSV53885421; called by muse, mutect2, varscan2
- CSMD3 | c.9792G>A p.E3264= (on ENST00000297405 / NM_001363185.1; = p.E3095= on NM_052900.3) | Silent (SNP) | VAF 50/534 reads (9%) | catalogued as rs765381502, COSV52289369; called by muse, mutect2
- CSPG4 | c.2046G>A p.L682= | Silent (SNP) | VAF 38/168 reads (23%) | called by muse, mutect2, varscan2
- CXCL12 | c.37C>T p.L13= | Silent (SNP) | VAF 32/226 reads (14%) | called by muse, varscan2
- DMRT3 | c.225C>A p.R75= | Silent (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2, varscan2
- DOK2 | c.519G>T p.R173= | Silent (SNP) | VAF 24/194 reads (12%) | catalogued as COSV52388350, COSV52389803; called by muse, mutect2, varscan2
- DPYS | c.21C>A p.L7= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV60906589; called by muse, mutect2, varscan2
- DST | c.10800C>A p.L3600= | Silent (SNP) | VAF 65/508 reads (13%) | called by muse, mutect2, varscan2
- DUSP5 | c.1092G>A p.V364= | Silent (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- DYSF | c.678G>A p.V226= | Silent (SNP) | VAF 37/245 reads (15%) | catalogued as rs201797348; called by muse, mutect2, varscan2
- EFHB | c.2184C>T p.D728= | Silent (SNP) | VAF 31/141 reads (22%) | called by muse, mutect2, varscan2
- FAM171A1 | c.1992G>A p.S664= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as rs144601840, COSV100968211; called by muse, mutect2, varscan2
- FAM180A | c.162G>T p.V54= | Silent (SNP) | VAF 30/265 reads (11%) | called by muse, mutect2, varscan2
- FAM181B | c.667C>A p.R223= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs756069214; called by muse, mutect2, varscan2
- FAM47A | c.1119C>G p.S373= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- FANCC | c.615C>T p.I205= | Silent (SNP) | VAF 69/438 reads (16%) | called by muse, mutect2, varscan2
- FER1L6 | c.4074C>A p.I1358= | Silent (SNP) | VAF 48/212 reads (23%) | called by muse, varscan2
- FGFR1 | c.177C>T p.D59= | Silent (SNP) | VAF 38/232 reads (16%) | catalogued as rs367880371; ClinVar: likely benign; called by muse, mutect2, varscan2
- FGFR3 | c.96G>T p.V32= | Silent (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- GABRD | c.153C>T p.Y51= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs148496176; called by muse, mutect2, varscan2
- GABRG1 | c.90G>T p.L30= | Silent (SNP) | VAF 52/351 reads (15%) | catalogued as COSV54956071; called by muse, mutect2, varscan2
- GALNT16 | c.583C>A p.R195= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV61887705; called by muse, mutect2, varscan2
- GAS2L1 | c.201C>T p.N67= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs749867915; called by muse, mutect2, varscan2
- GLYATL3 | c.693C>A p.A231= | Silent (SNP) | VAF 40/218 reads (18%) | called by muse, mutect2, varscan2
213 further variants in this file (0 protein-altering or splice-affecting, 127 silent, 86 other) are not listed here.
